Somatic mutation profile of tumor specimen 0DESUA from CCDI case PBBMCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.3 years (2,315 days).
Specimen 0DESUA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58a6dbdb-602a-41b8-839d-6c73d69c058f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DESUB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0031b7d-1649-4f68-944b-8355f86349d4

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD86 | c.676C>T p.R226W (on ENST00000330540 / NM_175862.5; = p.R220W on NM_006889.4) | Missense Mutation (SNP) | VAF 115/521 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs188841651, COSV52605374; called by muse, varscan2
- CIC | c.3922G>C p.E1308Q | Missense Mutation (SNP) | VAF 202/713 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.26); catalogued as rs371145542; called by muse, mutect2, varscan2
- DLGAP5 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 120/429 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751930287, COSV55964718; called by muse, mutect2, varscan2
- NPY1R | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 117/488 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.543); catalogued as COSV56713440; called by muse, mutect2, varscan2
- CRACR2B | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 155/609 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSSK1B | c.847G>C p.A283P | Missense Mutation (SNP) | VAF 188/780 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZXDC | c.2281del p.Q761Rfs*112 | Frame Shift Del (DEL) | VAF 150/759 reads (20%) | called by mutect2, pindel, varscan2
- GPCPD1 | c.651C>T p.Y217= | Silent (SNP) | VAF 170/596 reads (29%) | catalogued as rs1313388923, COSV66831347; called by muse, mutect2, varscan2
- THSD7B | c.3351A>G p.P1117= (on ENST00000272643; = p.P1115= on NM_001316349.2) | Silent (SNP) | VAF 156/563 reads (28%) | called by muse, mutect2, varscan2
- PSG1 | c.1243+409T>C | Intron (SNP) | VAF 126/492 reads (26%) | catalogued as rs776019002, COSV99741289; called by muse, mutect2, varscan2
